Somatic mutation profile of tumor specimen BA2451D (aliquot aq-BA2451D) from BEATAML1.0 case 2009, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.3 years (22,747 days).
Specimen BA2451D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9dedc9e2-38b1-4649-a28b-6bc08892707c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2291D (Solid Tissue Normal), aliquot aq-BA2291D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88bdfcf7-10a6-43d6-a421-fe58b7810668

The open-access MAF lists 24 somatic variants for this specimen: 14 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 7, Nonsense Mutation 2, Intron 1, 5'UTR 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4050C>A p.Y1350* (on ENST00000378444 / NM_001123385.2; = p.Y1316* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 31/54 reads (57%) | catalogued as COSV60699961, COSV60705362; called by muse, mutect2, varscan2
- CPT1A | c.1504G>A p.G502R | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355225127; called by muse, mutect2, varscan2
- CTTNBP2 | c.4044A>T p.Q1348H | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV99354251; called by muse, mutect2
- RIC1 | c.281A>G p.H94R | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as rs754193817; called by muse, mutect2, varscan2
- RUNX1 | c.586G>T p.E196* (on ENST00000344691 / NM_001001890.3; = p.E223* on NM_001754.5) | Nonsense Mutation (SNP) | VAF 51/136 reads (38%) | catalogued as COSV55868592, COSV99038731; called by muse, varscan2
- SYCP2 | c.4157C>T p.T1386M | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs145233078; called by muse, mutect2, varscan2
- TENM2 | c.1695C>A p.F565L (on ENST00000518659 / NM_001122679.2; = p.F333L on NM_001080428.3) | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.387); catalogued as COSV69122582; called by muse, mutect2
- TTBK1 | c.3674C>A p.A1225D | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.025); catalogued as rs569974338; called by muse, varscan2
- ZNF350 | c.1558G>A p.V520M | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs148220969; called by muse, mutect2, varscan2
- ACAN | c.1577C>T p.A526V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.458C>A p.A153E | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- FAM149A | c.942A>T p.R314S (on ENST00000356371 / NM_001367768.2; = p.R23S on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- STAG2 | c.2929_2930insTATT p.G977Vfs*8 | Frame Shift Ins (INS) | VAF 28/43 reads (65%) | called by mutect2, varscan2
- ZNF124 | c.856G>T p.A286S (on ENST00000543802 / NM_001297568.1; = p.A224S on NM_003431.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2
- CYLD | c.1914G>A p.E638= | Silent (SNP) | VAF 92/248 reads (37%) | catalogued as COSV61093570; called by muse, mutect2, varscan2
- F5 | c.6390C>A p.I2130= | Silent (SNP) | VAF 41/281 reads (15%) | called by muse, mutect2, varscan2
- GPIHBP1 | c.240G>A p.T80= | Silent (SNP) | VAF 39/94 reads (41%) | catalogued as rs144587519; called by muse, mutect2, varscan2
- LEUTX | c.378C>T p.A126= | Silent (SNP) | VAF 34/109 reads (31%) | catalogued as rs1389408322; called by muse, mutect2, varscan2
- MBD3L2 | c.555C>A p.A185= | Silent (SNP) | VAF 42/184 reads (23%) | called by muse, mutect2, varscan2
- SLC6A17 | c.267G>A p.L89= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV58996040; called by muse, mutect2
- VGF | c.1770G>T p.A590= | Silent (SNP) | VAF 7/107 reads (7%) | called by muse, mutect2
- FKBP9 | c.-35C>A | 5'UTR (SNP) | VAF 3/51 reads (6%) | called by muse, mutect2
- MUC2 | chr11:1099436 G>T | 5'Flank (SNP) | VAF 8/76 reads (11%) | catalogued as rs765317281; called by muse, varscan2
- MYOT | c.1325-48T>C | Intron (SNP) | VAF 16/202 reads (8%) | catalogued as rs572733740; called by muse, mutect2
